Somatic mutation profile of tumor specimen TARGET-30-PASUTC-01A (aliquot TARGET-30-PASUTC-01A-01D) from TARGET case TARGET-30-PASUTC, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.9 years (1,068 days).
Specimen TARGET-30-PASUTC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be586f4e-b8d4-4ae8-805a-15129bd2774a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASUTC-10A (Blood Derived Normal), aliquot TARGET-30-PASUTC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbc6b1ff-baa7-467c-bfec-920879b07a4e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3509T>G p.I1170S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66559499, COSV66566448, COSV66589132; called by muse, mutect2, varscan2
- MYH4 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRUNE2 | c.4282G>T p.D1428Y | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2
